CCDI case PBCLCG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9115ce90-adfb-45cd-afb7-be8f0f19937c

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pineoblastoma: ICD-O-3 morphology code: 9362/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.7 years (1,340 days).

Biospecimens (2 samples)
- Sample 0DUETM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUETV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
